TCGA case TCGA-63-7023 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Ontario Institute for Cancer Research. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/31d8591b-9d80-406c-b61a-7a6544c73466

Demographics
Sex at birth: male; Country of residence at enrollment: Canada; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,682 days (4.6 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 1; Treatment dose: 184 mg; Prescribed dose: 92; Prescribed dose units: mg/day; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment dose: 5,000 cGy; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Treatment intent type: Adjuvant; Number of cycles: 1; Treatment dose: 92 mg; Prescribed dose: 46; Prescribed dose units: mg/day; Route of administration: Intravenous.

Follow-up (3 entries)
- Days to follow up: 1,682 days (4.6 years); Disease response: Tumor Free.
- ECOG performance status: 1; Timepoint: Other.
- Disease response: Tumor Free; Timepoint: Follow-up.

Other clinical attributes
- DLCO (% of predicted): 70; FEV1 before bronchodilator (% of reference): 87.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 55; Tobacco smoking onset year: 1952; Tobacco smoking quit year: 2008.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-63-7023-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-63-7023-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 83; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
  Slide TCGA-63-7023-01A-01-BS1: Section location: Bottom; Percent tumor cells: 62; Percent tumor nuclei: 58; Percent normal cells: 33; Percent necrosis: 4; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
- Sample TCGA-63-7023-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-63-7023-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Lower; Location lung parenchyma: Central Lung; Pulmonary function test indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,682 days; disease-specific survival: no event (censored), 1,682 days; disease-free interval: no event (censored), 1,682 days; progression-free interval: no event (censored), 1,682 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-63-7023-01A-11D-1943-01): tumor purity 0.85, ploidy 1.92, whole-genome doublings 0.
